Surgical pathology report (de-identified scan), TCGA case TCGA-QB-A6FS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Emory University, specimen TCGA-QB-A6FS-06A (Metastatic).

[page 1 of 3]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:
Contributor system:

* Final Report *

(Verified)

ICD-6-3
Melanoma, malignant
8720/3
Site Inguinal lymph node
C77.4
JW 6/17/13

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender:

M

Acc #:

(Age:)

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LYMPH NODES, INGUINAL CANAL, LYMPHADENECTOMY:

- 1 LYMPH NODE, NO TUMOR SEEN.

B. LYMPH NODES, LEFT INGUINAL CONTENTS, LYMPHADENECTOMY:

- MASS OF METASTATIC MELANOMA (10.7 CM) INVOLVING LYMPH NODE(S); THIS MAY REPRESENT MULTIPLE

MATTED NODES (INDETERMINATE FOR EXTRANODAL EXTENSION).

- 7 ADDITIONAL BENIGN LYMPH NODES.

C. LYMPH NODES, CLOQUET'S NODES, LYMPHADENECTOMY:

- 3 LYMPH NODES, NO TUMOR SEEN.

D. LYMPH NODES, LEFT EXTERNAL ILIAC, LYMPHADENECTOMY:

- 12 LYMPH NODES, NO TUMOR SEEN.

Printed by:

Printed on:

Page 1 of 3
(Continued)

IVUSA Discrepancy		
Pre-Melanoma History		
Concurrent Primary Sites		
Case is (re)classified		
Re-review criteria		

hw 6/11/13
MB 5/24/13

[page 2 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

E. LYMPH NODES, LEFT OBTURATOR, LYMPHADENECTOMY: - 5 LYMPH NODES, NO TUMOR SEEN.

Electronically Signed by

Clinical History

Left pelvic lymphadenectomy. Melanoma.

Specimen(s) Received

- A: Inguinal canal lymph node
- B: Left inguinal contents
- C: Cloquet's node
- D: Left external iliac node
- E: Left obturator node

Gross Description

The specimen is received fresh in five parts, each in formalin and labeled with the patient's name and medical record number.

Specimen A is further labeled "inguinal canal lymph nodes" and consists of a portion of fatty tissue measuring 2.0 x 1.5 x 0.8 cm. A lymph node is identified within the fat measuring 1.5 x 1.0 x 0.6 cm. The lymph node is bisected and submitted, "A1." Dictated by

Specimen B is further labeled "left inguinal contents." Received is a firm mass covered with fatty tissue measuring 10.2 x 10.2 x 5.6 cm and weighing 354 grams. The specimen is inked black. The mass upon sectioning has a grey-black to tan lobular cut surface with necrotic areas consistent with lymph node (possibly multiple lymph nodes) and measuring 10.7 x 8.8 x 5.7 cm. Seven additional grey-black lymph nodes are identified ranging from 0.7 x 0.6 x 0.5 cm up to 4.7 x 1.7 x 1.2 cm. A representative sample from the largest lymph node is submitted to Sections are submitted as follows: Dictated by

Specimen C is further labeled "Cloquet's nodes" and consists of a portion of fatty tissue measuring 1.8 x 1.7 x 1.2 cm. Within the fatty tissue, three grey-black lymph nodes are identified ranging from 0.2 x 0.2 x 0.1 cm up to 1.3 x 0.7 x 0.6 cm. The largest lymph node is bisected and submitted, "C1." The two smaller lymph nodes are submitted, "C2." Dictated by

Specimen D is further labeled "left external iliac nodes" and consists of two portions of fatty tissue measuring 7.3 x 5.6 x 2.4 cm. Within the fatty tissue, twelve grey-black lymph nodes are identified ranging from 0.3 x 0.3 x 0.2 cm up to 5.6 x 2.4 x 1.4 cm. The lymph nodes are submitted as follows: Dictated by

Specimen E is further labeled "left obturator nodes" and consists of a single portion of fatty tissue measuring 10.5 x 3.3 x 1.8 cm. Five lymph nodes are identified within the fatty tissue ranging from 0.4 x 0.3 x 0.3 cm up to 8.8 x 2.3 x 1.2 cm. The lymph nodes are submitted as follows: Dictated by

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

CASSETTE SUMMARY:

B1,B2:	Representative sections, largest lymph node
B3:	Representative section, second largest lymph node
B4:	One lymph node, bisected
B5:	One lymph node, bisected
B6:	One lymph node, bisected
B7:	Two lymph nodes, each bisected, one inked blue
B8:	One lymph node, whole
B9-B11:	Remainder of second largest lymph node
D1:	Representative sections, largest lymph node
D2:	Two lymph nodes, each bisected, one inked blue
D3:	Two lymph nodes, each bisected, one inked blue
D4:	One lymph node, bisected
D5:	Two lymph nodes, whole
D6:	Four lymph nodes, whole
D7-D10:	Remainder of largest lymph node
E1,E2:	Representative sections, largest lymph node
E3:	One lymph node, bisected
E4:	One lymph node, bisected
E5:	Two lymph nodes, whole
E6-E15:	Remainder of largest lymph node

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 7c47afbd-009f-4cf7-87cf-4f92f7d5398a (TCGA-QB-A6FS.FEB2C1FD-2611-41B3-A240-666D61B9A580.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).